Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7689, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7689-01A (Primary Tumor).

Microscopic

Sections demonstrate a mildly to moderately hypercellular infiltrating glial neoplasm characterized by neoplastic cells with round, enlarged nuclei and perinuclear halos. Several areas demonstrate many gemistocytic cells with eosinophilic cytoplasm and eccentrically placed nuclei. There is a myxoid to macrocystic background with thin, delicate branching capillaries. No microvascular proliferation or necrosis are identified. A rare mitotic figure is seen.

Diagnosis

Low grade oligodendroglioma grade II

Source: NCI Genomic Data Commons file b2ef699a-b996-4d46-a48c-8748d3eae3c7 (TCGA-HT-7689.21E316FB-FD2B-4890-A34A-832781031216.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).